CCDI case PBCBKT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/ef4baa0f-6e12-4593-a426-492b16080b0f

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Endocervix; Age at diagnosis: 18.5 years (6,755 days).

Biospecimens (3 samples)
- Sample 0DO5DW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DO5EV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DO5FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
